Somatic mutation profile of tumor specimen C3N-04294-01 (aliquot CPT0244730009) from CPTAC case C3N-04294, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIID; Age at diagnosis: 64.0 years (23,388 days).
Specimen C3N-04294-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Lymph Node; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e3b95894-f03c-477f-945a-fc2e4ac544ac.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-04294-31 (Blood Derived Normal), aliquot CPT0244750002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/98cfb051-ac30-4a48-9cca-e2b9b11a3399

The open-access MAF lists 257 somatic variants for this specimen: 163 protein-altering or splice-affecting, 83 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 143, Silent 83, Nonsense Mutation 9, Intron 5, Frame Shift Ins 4, 5'Flank 4, Splice Site 3, Frame Shift Del 3, Splice Region 1, 3'UTR 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 234/342 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- ABCA12 | c.1301G>A p.R434Q (on ENST00000272895 / NM_173076.3; = p.R116Q on NM_015657.3) | Missense Mutation (SNP) | VAF 71/243 reads (29%) | SIFT tolerated (0.42); PolyPhen benign (0.01); catalogued as rs745415552, COSV55947973; called by muse, mutect2, varscan2
- ABCB10 | c.2011C>T p.L671F | Missense Mutation (SNP) | VAF 105/349 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.087); catalogued as COSV100747833; called by muse, mutect2, varscan2
- ACLY | c.1451C>T p.S484F | Missense Mutation (SNP) | VAF 147/468 reads (31%) | SIFT tolerated (0.05); PolyPhen benign (0.039); catalogued as rs375642586; called by muse, mutect2, varscan2
- ADAMTS18 | c.1523A>G p.D508G | Missense Mutation (SNP) | VAF 129/457 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.031); catalogued as COSV51417931; called by muse, mutect2, varscan2
- AP4M1 | c.898C>T p.P300S | Missense Mutation (SNP) | VAF 122/450 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.127); catalogued as rs774391984; called by muse, mutect2, varscan2
- APBA3 | c.1531C>T p.R511C | Missense Mutation (SNP) | VAF 107/414 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs981949974; called by muse, mutect2, varscan2
- BRWD3 | c.2095C>T p.R699* | Nonsense Mutation (SNP) | VAF 102/177 reads (58%) | catalogued as COSV64746018; called by muse, mutect2, varscan2
- C14orf39 | c.508C>T p.R170* | Nonsense Mutation (SNP) | VAF 64/201 reads (32%) | catalogued as rs754275662, COSV58783614; called by muse, mutect2, varscan2
- C8orf34 | c.904G>A p.E302K | Missense Mutation (SNP) | VAF 108/339 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.295); catalogued as COSV61374150; called by muse, mutect2, varscan2
- CARD11 | c.1750C>T p.R584C | Missense Mutation (SNP) | VAF 163/446 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as rs1251262286, COSV62756526; called by muse, mutect2, varscan2
- CDH1 | c.1519T>C p.S507P | Missense Mutation (SNP) | VAF 158/400 reads (40%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.719); catalogued as rs1402430481; called by muse, mutect2, varscan2
- CDH7 | c.1213G>A p.D405N | Missense Mutation (SNP) | VAF 92/289 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV59894320; called by muse, mutect2, varscan2
- CDRT1 | c.539C>T p.S180F | Missense Mutation (SNP) | VAF 111/360 reads (31%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV55412976; called by muse, mutect2, varscan2
- CEACAM6 | c.502G>A p.E168K | Missense Mutation (SNP) | VAF 154/523 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.251); catalogued as COSV52267617; called by muse, mutect2, varscan2
- CFHR2 | c.349G>A p.G117R | Missense Mutation (SNP) | VAF 134/470 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66380713; called by muse, mutect2, varscan2
- CFHR5 | c.628C>T p.P210S | Missense Mutation (SNP) | VAF 72/290 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.069); catalogued as rs758964255, COSV56817965; called by muse, mutect2, varscan2
- CLEC2B | c.351G>A p.M117I | Missense Mutation (SNP) | VAF 85/319 reads (27%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as COSV57309734; called by muse, mutect2, varscan2
- DNAH2 | c.2614G>A p.D872N | Missense Mutation (SNP) | VAF 100/369 reads (27%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs1312696438; called by muse, mutect2, varscan2
- DNAH7 | c.5621G>A p.R1874Q | Missense Mutation (SNP) | VAF 85/313 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.775); catalogued as rs1274108178, COSV56774235; called by muse, mutect2
- DOCK3 | c.2964G>A p.M988I | Missense Mutation (SNP) | VAF 121/460 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1288443885; called by muse, mutect2, varscan2
- DSG3 | c.700C>T p.R234C | Missense Mutation (SNP) | VAF 58/245 reads (24%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.806); catalogued as rs772960249, COSV57124134; called by muse, varscan2
- DTX3 | c.781C>T p.P261S | Missense Mutation (SNP) | VAF 122/451 reads (27%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV54090894; called by muse, mutect2, varscan2
- F5 | c.1614G>A p.R538= | Splice Region (SNP) | VAF 71/255 reads (28%) | catalogued as COSV63122211; called by muse, mutect2, varscan2
- FAM135B | c.1699G>A p.E567K | Missense Mutation (SNP) | VAF 121/432 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.439); catalogued as rs772418841, COSV52715727; called by muse, mutect2, varscan2
- GFOD1 | c.493G>A p.D165N | Missense Mutation (SNP) | VAF 161/589 reads (27%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.867); catalogued as rs746909529; called by muse, mutect2, varscan2
- KCNQ5 | c.2726G>A p.R909Q | Missense Mutation (SNP) | VAF 107/369 reads (29%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.203); catalogued as rs184951305, COSV100573017; called by muse, mutect2, varscan2
- MAGEC1 | c.199C>T p.L67F | Missense Mutation (SNP) | VAF 144/258 reads (56%) | SIFT tolerated, low confidence (0.14); PolyPhen possibly damaging (0.86); catalogued as COSV53579372; called by muse, mutect2, varscan2
- MARCHF4 | c.122G>A p.R41H | Missense Mutation (SNP) | VAF 162/506 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.028); catalogued as rs910030817, COSV56104657, COSV56104825; called by muse, mutect2, varscan2
- MECOM | c.2719G>A p.D907N (on ENST00000468789 / NM_001105078.4; = p.D1095N on NM_004991.4) | Missense Mutation (SNP) | VAF 117/392 reads (30%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs1209999207, COSV52976640; called by muse, mutect2, varscan2
- MEPE | c.1123C>T p.P375S | Missense Mutation (SNP) | VAF 113/297 reads (38%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.98); catalogued as COSV100734964; called by muse, mutect2, varscan2
- MGAM | c.4736C>T p.P1579L | Missense Mutation (SNP) | VAF 416/626 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1220493332; called by muse, mutect2, varscan2
- MPP7 | c.1030G>A p.D344N | Missense Mutation (SNP) | VAF 111/391 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV100516946; called by muse, mutect2, varscan2
- MYC | c.733C>T p.P245S (on ENST00000377970; = p.P260S on NM_002467.6) | Missense Mutation (SNP) | VAF 38/318 reads (12%) | SIFT tolerated (0.66); PolyPhen possibly damaging (0.559); catalogued as COSV52381674, COSV99418971; called by muse, mutect2, varscan2
- MYH4 | c.2065G>A p.E689K | Missense Mutation (SNP) | VAF 102/380 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.027); catalogued as rs1257710906; called by muse, mutect2, varscan2
- NBEA | c.4654C>T p.R1552W | Missense Mutation (SNP) | VAF 60/185 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs1383053577, COSV59816267; called by muse, mutect2, varscan2
- NCOA6 | c.1129C>T p.P377S | Missense Mutation (SNP) | VAF 164/489 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62866009; called by muse, mutect2, varscan2
- NLRP4 | c.190G>A p.E64K | Missense Mutation (SNP) | VAF 129/466 reads (28%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.946); catalogued as COSV56711027; called by muse, mutect2, varscan2
- NR2C1 | c.302C>T p.S101F | Missense Mutation (SNP) | VAF 64/234 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.046); catalogued as rs772209882; called by muse, mutect2, varscan2
- NRK | c.1694C>T p.A565V | Missense Mutation (SNP) | VAF 193/301 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99689560; called by muse, mutect2, varscan2
- OTOP3 | c.739G>A p.E247K | Missense Mutation (SNP) | VAF 56/226 reads (25%) | SIFT tolerated (0.43); PolyPhen benign (0.015); catalogued as rs867239064, COSV60912216; called by muse, mutect2, varscan2
- PCDHA5 | c.2329C>T p.Q777* | Nonsense Mutation (SNP) | VAF 125/424 reads (29%) | catalogued as COSV65351342; called by muse, mutect2, varscan2
- PCDHB7 | c.2090C>T p.S697L | Missense Mutation (SNP) | VAF 222/1537 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.239); catalogued as COSV50774843; called by muse, mutect2, varscan2
- PDE1C | c.1397G>A p.R466K | Missense Mutation (SNP) | VAF 148/375 reads (39%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.926); catalogued as COSV58514767; called by muse, mutect2, varscan2
- PKD2L1 | c.901G>A p.V301M | Missense Mutation (SNP) | VAF 141/308 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.792); catalogued as rs1420686359, COSV104402449; called by muse, mutect2, varscan2
- PPP1R13L | c.1657C>T p.R553C | Missense Mutation (SNP) | VAF 213/728 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs750806921, COSV100714888, COSV62907828; called by muse, mutect2, varscan2
- PPP1R16B | c.1162G>A p.E388K | Missense Mutation (SNP) | VAF 141/429 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.4); catalogued as rs1231674795; called by muse, mutect2, varscan2
- RADX | c.1903C>T p.P635S | Missense Mutation (SNP) | VAF 64/113 reads (57%) | SIFT tolerated (0.41); PolyPhen benign (0.025); catalogued as COSV65319941; called by muse, mutect2, varscan2
- RBPMS2 | c.155G>A p.R52Q | Missense Mutation (SNP) | VAF 111/369 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.791); catalogued as rs575548719; called by muse, mutect2, varscan2
- REG3G | c.94G>A p.E32K | Missense Mutation (SNP) | VAF 95/355 reads (27%) | SIFT tolerated (0.32); PolyPhen benign (0.024); catalogued as COSV55449665; called by muse, mutect2, varscan2
- RGPD3 | c.5200C>T p.P1734S | Missense Mutation (SNP) | VAF 140/516 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.989); catalogued as rs1199802731, COSV58738567; called by muse, mutect2, varscan2
- ROS1 | c.3507G>A p.M1169I | Missense Mutation (SNP) | VAF 88/306 reads (29%) | SIFT tolerated (0.97); PolyPhen benign (0.006); catalogued as COSV63859217; called by muse, mutect2, varscan2
- RP1 | c.4757C>T p.P1586L | Missense Mutation (SNP) | VAF 137/465 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.826); catalogued as COSV55117423; called by muse, mutect2, varscan2
- RSPO3 | c.666dup p.P223Tfs*2 | Frame Shift Ins (INS) | VAF 46/162 reads (28%) | catalogued as rs1049009076; called by mutect2, varscan2
- SKAP1 | c.377C>T p.S126L | Missense Mutation (SNP) | VAF 75/267 reads (28%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.964); catalogued as rs368601769; called by muse, mutect2, varscan2
- SMAD6 | c.1448C>T p.S483F | Missense Mutation (SNP) | VAF 101/323 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1181448110; called by muse, mutect2, varscan2
- SRGAP3 | c.2309C>T p.S770L | Missense Mutation (SNP) | VAF 178/548 reads (32%) | SIFT tolerated (0.27); PolyPhen benign (0.098); catalogued as rs753859975, COSV64540402; called by muse, mutect2, varscan2
- THOP1 | c.8C>T p.P3L | Missense Mutation (SNP) | VAF 130/445 reads (29%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.099); catalogued as rs1328730571; called by muse, mutect2, varscan2
- TMEM116 | c.24G>C p.Q8H | Missense Mutation (SNP) | VAF 96/319 reads (30%) | SIFT tolerated (0.64); PolyPhen benign (0.001); catalogued as rs1410121020; called by muse, mutect2, varscan2
- TSEN54 | c.749C>T p.P250L | Missense Mutation (SNP) | VAF 146/487 reads (30%) | SIFT tolerated (0.22); PolyPhen benign (0.039); catalogued as rs866930562; called by muse, varscan2
- TTN | c.51650G>A p.R17217Q (on ENST00000591111; = p.R9793Q on NM_003319.4) | Missense Mutation (SNP) | VAF 128/454 reads (28%) | PolyPhen possibly damaging (0.455); catalogued as rs755848019, COSV59925937, COSV59994352; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TTN | c.42559G>A p.E14187K (on ENST00000591111; = p.E6763K on NM_003319.4) | Missense Mutation (SNP) | VAF 141/424 reads (33%) | PolyPhen probably damaging (0.994); catalogued as rs1246983682; called by muse, mutect2, varscan2
- TTN | c.17134G>A p.V5712I (on ENST00000591111; = p.V4785I on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 132/429 reads (31%) | PolyPhen probably damaging (0.99); catalogued as rs1274174149; called by muse, mutect2, varscan2
- TUBGCP6 | c.1241C>T p.S414F | Missense Mutation (SNP) | VAF 170/501 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs747979891; called by muse, mutect2, varscan2
- UPK1A | c.701C>T p.S234L | Missense Mutation (SNP) | VAF 130/404 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.677); catalogued as rs375272541; called by muse, mutect2, varscan2
- UTRN | c.3409A>T p.M1137L | Missense Mutation (SNP) | VAF 112/464 reads (24%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.96); catalogued as rs539582140; called by muse, mutect2, varscan2
- ZDHHC4 | c.760C>T p.P254S | Missense Mutation (SNP) | VAF 186/475 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs976844091, COSV60106684; called by muse, mutect2, varscan2
- ZNF185 | c.1252G>C p.G418R | Missense Mutation (SNP) | VAF 151/249 reads (61%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as COSV59274942; called by muse, mutect2, varscan2
- ZNF2 | c.1063C>T p.Q355* (on ENST00000611147 / NM_001291605.2; = p.Q342* on NM_021088.4) | Nonsense Mutation (SNP) | VAF 124/432 reads (29%) | catalogued as rs751713686; called by muse, mutect2, varscan2
- ZNF257 | c.1033C>A p.Q345K | Missense Mutation (SNP) | VAF 100/384 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs555293490, COSV71310222, COSV71312175, COSV71312346; called by mutect2, varscan2
- ZNF514 | c.818C>T p.S273L | Missense Mutation (SNP) | VAF 148/529 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.838); catalogued as rs367936062; called by muse, mutect2, varscan2
- ZNF517 | c.1043G>A p.G348D | Missense Mutation (SNP) | VAF 189/683 reads (28%) | SIFT tolerated (0.2); PolyPhen benign (0.006); catalogued as rs749435416; called by muse, mutect2, varscan2
- ACY3 | c.407C>T p.A136V | Missense Mutation (SNP) | VAF 90/191 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- ADAM2 | c.253G>A p.D85N | Missense Mutation (SNP) | VAF 93/311 reads (30%) | SIFT tolerated (0.27); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- ADGRG6 | c.2051C>T p.S684L | Missense Mutation (SNP) | VAF 88/382 reads (23%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- AMPD2 | c.1034C>T p.A345V | Missense Mutation (SNP) | VAF 84/195 reads (43%) | SIFT tolerated (0.11); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- ANXA6 | c.1352C>T p.A451V | Missense Mutation (SNP) | VAF 64/238 reads (27%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.857); called by muse, varscan2
- ARFGEF3 | c.2786-1G>A p.X929_splice | Splice Site (SNP) | VAF 67/270 reads (25%) | called by muse, mutect2, varscan2
- ARFGEF3 | c.2786G>A p.G929D | Missense Mutation (SNP) | VAF 67/271 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ARMH1 | c.88C>T p.H30Y | Missense Mutation (SNP) | VAF 58/283 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.346); called by muse, mutect2, varscan2
- BCL11A | c.1211C>T p.S404F (on ENST00000335712 / NM_001365609.1; = p.S438F on NM_018014.4) | Missense Mutation (SNP) | VAF 149/539 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- BCORL1 | c.899C>T p.P300L | Missense Mutation (SNP) | VAF 205/358 reads (57%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.14); called by muse, mutect2, varscan2
- C5orf24 | c.283G>A p.G95R | Missense Mutation (SNP) | VAF 137/476 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- C7orf25 | c.1055C>T p.S352L | Missense Mutation (SNP) | VAF 209/639 reads (33%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.832); called by muse, mutect2, varscan2
- CACNA1A | c.1861C>T p.L621F | Missense Mutation (SNP) | VAF 110/382 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- CDRT1 | c.880G>A p.D294N | Missense Mutation (SNP) | VAF 131/431 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CEP295 | c.7517A>G p.H2506R | Missense Mutation (SNP) | VAF 76/181 reads (42%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- CFH | c.3003G>A p.M1001I | Missense Mutation (SNP) | VAF 124/388 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CNN2 | c.644G>A p.C215Y | Missense Mutation (SNP) | VAF 85/293 reads (29%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- CNR2 | c.413C>T p.P138L | Missense Mutation (SNP) | VAF 162/350 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, varscan2
- COL5A1 | c.4085C>T p.P1362L | Missense Mutation (SNP) | VAF 143/515 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.321); called by muse, mutect2
- COPG2 | c.2227G>A p.G743R | Missense Mutation (SNP) | VAF 278/410 reads (68%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- CYP26B1 | c.569T>C p.F190S | Missense Mutation (SNP) | VAF 176/587 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- CYP26B1 | c.568T>C p.F190L | Missense Mutation (SNP) | VAF 178/595 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.812); called by muse, mutect2, varscan2
- DACT2 | c.661G>A p.D221N | Missense Mutation (SNP) | VAF 147/306 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DALRD3 | c.125C>A p.A42E | Missense Mutation (SNP) | VAF 85/564 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.69); called by muse, mutect2, varscan2
- DNAH14 | c.5242G>A p.E1748K (on ENST00000445597; = p.E2153K on NM_001367479.1) | Missense Mutation (SNP) | VAF 49/140 reads (35%) | SIFT tolerated (0.36); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- DNAH6 | c.3175-1G>A p.X1059_splice | Splice Site (SNP) | VAF 90/271 reads (33%) | called by muse, mutect2, varscan2
- DOCK11 | c.2261C>T p.P754L | Missense Mutation (SNP) | VAF 86/130 reads (66%) | SIFT tolerated (0.37); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DSCAM | c.5025G>A p.M1675I | Missense Mutation (SNP) | VAF 79/415 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.164); called by muse, mutect2, varscan2
- EDEM1 | c.146_147dup p.D50Pfs*125 | Frame Shift Ins (INS) | VAF 164/578 reads (28%) | called by mutect2, pindel, varscan2
- EIF2B4 | c.118C>T p.R40W | Missense Mutation (SNP) | VAF 111/486 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- FAT2 | c.6988G>A p.E2330K | Missense Mutation (SNP) | VAF 153/524 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.366); called by muse, mutect2, varscan2
- FBXL5 | c.1925C>T p.A642V | Missense Mutation (SNP) | VAF 13/395 reads (3%) | SIFT tolerated (0.51); PolyPhen benign (0.012); called by muse, mutect2
- FBXO24 | c.1535C>T p.P512L (on ENST00000241071 / NM_033506.3; = p.P550L on NM_012172.5) | Missense Mutation (SNP) | VAF 225/751 reads (30%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- FRMPD2 | c.1811C>T p.T604I | Missense Mutation (SNP) | VAF 72/165 reads (44%) | SIFT tolerated (0.47); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- FZD5 | c.1525_1529del p.M509Pfs*88 | Frame Shift Del (DEL) | VAF 161/554 reads (29%) | called by mutect2, pindel, varscan2
- GATA3 | c.1095C>A p.N365K | Missense Mutation (SNP) | VAF 129/412 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HMCN2 | c.13019G>A p.G4340D | Missense Mutation (SNP) | VAF 159/557 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ITGB1 | c.2161C>T p.P721S | Missense Mutation (SNP) | VAF 54/195 reads (28%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.601); called by muse, mutect2, varscan2
- KNTC1 | c.1058C>T p.S353F | Missense Mutation (SNP) | VAF 60/221 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- LGALS16 | c.253G>T p.D85Y | Missense Mutation (SNP) | VAF 96/329 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LGMN | c.56C>T p.P19L | Missense Mutation (SNP) | VAF 109/379 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- LLGL2 | c.2264G>A p.R755K | Missense Mutation (SNP) | VAF 158/563 reads (28%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.49); called by muse, mutect2
- LMLN | c.1352C>T p.P451L | Missense Mutation (SNP) | VAF 73/266 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MAMDC2 | c.820G>A p.E274K | Missense Mutation (SNP) | VAF 187/592 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MEIS1 | c.587C>T p.S196L | Missense Mutation (SNP) | VAF 115/447 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.313); called by muse, mutect2, varscan2
- MUC16 | c.31705G>A p.A10569T | Missense Mutation (SNP) | VAF 121/446 reads (27%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- MUC17 | c.12268A>G p.T4090A | Missense Mutation (SNP) | VAF 255/657 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MUC22 | c.3776C>T p.S1259F | Missense Mutation (SNP) | VAF 344/797 reads (43%) | SIFT tolerated (0.06); called by muse, mutect2, varscan2
- NEB | c.16343C>T p.S5448L | Missense Mutation (SNP) | VAF 77/285 reads (27%) | SIFT tolerated (0.3); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- PCDHGB2 | c.112C>T p.P38S | Missense Mutation (SNP) | VAF 114/397 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.981); called by muse, varscan2
- PENK | c.764C>T p.P255L | Missense Mutation (SNP) | VAF 111/349 reads (32%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.858); called by muse, mutect2, varscan2
- PLCB1 | c.3364G>A p.E1122K | Missense Mutation (SNP) | VAF 74/259 reads (29%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.829); called by muse, mutect2, varscan2
- PLCE1 | c.232G>A p.E78K | Missense Mutation (SNP) | VAF 125/288 reads (43%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0); called by muse, mutect2, varscan2
- POU2F2 | c.1399G>A p.G467S (on ENST00000526816 / NM_001207025.3; = p.G451S on NM_002698.5) | Missense Mutation (SNP) | VAF 120/341 reads (35%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- PRAMEF1 | c.1281G>A p.W427* | Nonsense Mutation (SNP) | VAF 92/550 reads (17%) | called by muse, mutect2
- PRAMEF2 | c.1281G>A p.W427* | Nonsense Mutation (SNP) | VAF 22/146 reads (15%) | called by muse, mutect2
- PRDM9 | c.284G>A p.W95* | Nonsense Mutation (SNP) | VAF 96/303 reads (32%) | called by muse, mutect2, varscan2
- PRPSAP1 | c.652G>A p.E218K | Missense Mutation (SNP) | VAF 111/324 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- PSMG1 | c.424G>A p.A142T | Missense Mutation (SNP) | VAF 97/438 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RAB11FIP3 | c.76G>A p.G26R | Missense Mutation (SNP) | VAF 143/434 reads (33%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- RBMS2 | c.251C>T p.S84F | Missense Mutation (SNP) | VAF 79/348 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RELCH | c.3473C>T p.S1158F | Missense Mutation (SNP) | VAF 79/257 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RGS12 | c.1877A>G p.K626R | Missense Mutation (SNP) | VAF 42/102 reads (41%) | SIFT tolerated (0.15); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- RNF2 | c.249-1G>T p.X83_splice | Splice Site (SNP) | VAF 60/178 reads (34%) | called by muse, mutect2, varscan2
- RPGRIP1L | c.3445del p.I1149Ffs*6 | Frame Shift Del (DEL) | VAF 65/242 reads (27%) | called by mutect2, pindel, varscan2
- RTL6 | c.436G>A p.G146R | Missense Mutation (SNP) | VAF 148/555 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SAG | c.968C>T p.T323I | Missense Mutation (SNP) | VAF 88/365 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.816); called by muse, mutect2, varscan2
- SALL3 | c.562G>A p.A188T | Missense Mutation (SNP) | VAF 200/694 reads (29%) | SIFT tolerated (0.36); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SALL3 | c.767G>A p.S256N | Missense Mutation (SNP) | VAF 57/200 reads (29%) | SIFT tolerated (0.32); PolyPhen benign (0); called by muse, mutect2, varscan2
- SCARA3 | c.328C>T p.P110S | Missense Mutation (SNP) | VAF 91/270 reads (34%) | SIFT tolerated (0.52); PolyPhen benign (0); called by muse, mutect2, varscan2
- SHANK3 | c.4759G>A p.A1587T | Missense Mutation (SNP) | VAF 16/503 reads (3%) | SIFT tolerated (0.47); PolyPhen benign (0); called by muse, mutect2
- SLC6A15 | c.1496T>C p.V499A | Missense Mutation (SNP) | VAF 57/232 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.291); called by muse, mutect2, varscan2
- SPATA18 | c.155G>A p.G52E | Missense Mutation (SNP) | VAF 126/301 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- STARD6 | c.448C>T p.P150S | Missense Mutation (SNP) | VAF 62/319 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.305); called by muse, mutect2
- TAAR6 | c.784dup p.V262Gfs*14 | Frame Shift Ins (INS) | VAF 116/430 reads (27%) | called by mutect2, pindel, varscan2
- TAAR9 | c.610C>T p.L204F | Missense Mutation (SNP) | VAF 110/335 reads (33%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.466); called by muse, mutect2, varscan2
- TEX35 | c.265G>A p.E89K | Missense Mutation (SNP) | VAF 94/327 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.889); called by muse, mutect2, varscan2
- THSD7B | c.4432G>A p.A1478T (on ENST00000272643; = p.A1476T on NM_001316349.2) | Missense Mutation (SNP) | VAF 103/387 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- TMEM131L | c.1974dup p.E659Rfs*11 | Frame Shift Ins (INS) | VAF 103/281 reads (37%) | called by mutect2, pindel, varscan2
- TRAV12-2 | c.70G>A p.E24K | Missense Mutation (SNP) | VAF 51/209 reads (24%) | SIFT tolerated (0.32); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- TTN | c.47671G>A p.D15891N (on ENST00000591111; = p.D8467N on NM_003319.4) | Missense Mutation (SNP) | VAF 131/453 reads (29%) | PolyPhen benign (0.073); called by muse, mutect2, varscan2
- TXLNB | c.1456C>T p.Q486* | Nonsense Mutation (SNP) | VAF 110/401 reads (27%) | called by muse, mutect2, varscan2
- TXNDC2 | c.1080del p.K361Sfs*33 (on ENST00000306084 / NM_001098529.2; = p.K294Sfs*33 on NM_032243.6) | Frame Shift Del (DEL) | VAF 138/555 reads (25%) | called by mutect2, pindel, varscan2
- VWDE | c.1240C>T p.Q414* | Nonsense Mutation (SNP) | VAF 130/301 reads (43%) | called by muse, mutect2, varscan2
- WNT5A | c.449T>A p.M150K | Missense Mutation (SNP) | VAF 121/404 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.069); called by mutect2, varscan2
- XPO6 | c.2794C>T p.P932S | Missense Mutation (SNP) | VAF 77/280 reads (28%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.503); called by muse, mutect2, varscan2
- ZFHX2 | c.7672G>A p.D2558N | Missense Mutation (SNP) | VAF 113/378 reads (30%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.622); called by muse, mutect2, varscan2
- ZNF175 | c.1689A>T p.E563D | Missense Mutation (SNP) | VAF 145/433 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF541 | c.250G>A p.D84N | Missense Mutation (SNP) | VAF 136/443 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ZNF696 | c.922C>T p.L308F | Missense Mutation (SNP) | VAF 243/786 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- ZNF713 | c.718C>T p.H240Y (on ENST00000633730 / NM_001366796.2; = p.H253Y on NM_182633.3) | Missense Mutation (SNP) | VAF 129/390 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.857); called by muse, mutect2, varscan2
- AC099489.1 | c.5142C>T p.F1714= | Silent (SNP) | VAF 98/360 reads (27%) | called by muse, mutect2, varscan2
- ACACA | c.3147C>T p.A1049= | Silent (SNP) | VAF 95/366 reads (26%) | called by muse, mutect2, varscan2
- ACTN4 | c.2526G>A p.T842= | Silent (SNP) | VAF 145/481 reads (30%) | catalogued as rs375763862; called by muse, mutect2, varscan2
- ADAMTS20 | c.4488G>A p.R1496= | Silent (SNP) | VAF 93/326 reads (29%) | called by muse, mutect2, varscan2
- AMER3 | c.1068G>A p.R356= | Silent (SNP) | VAF 178/578 reads (31%) | catalogued as COSV58465984; called by muse, mutect2, varscan2
- AMPD2 | c.1035C>T p.A345= | Silent (SNP) | VAF 84/193 reads (44%) | catalogued as rs574448906; called by muse, mutect2, varscan2
- ATRNL1 | c.1566C>T p.Y522= | Silent (SNP) | VAF 78/223 reads (35%) | catalogued as rs1236352492, COSV61802152; called by muse, mutect2, varscan2
- CBR3 | c.381G>C p.P127= | Silent (SNP) | VAF 93/408 reads (23%) | catalogued as COSV51742495; called by muse, mutect2, varscan2
- CCL11 | c.183T>A p.A61= | Silent (SNP) | VAF 57/218 reads (26%) | called by muse, mutect2, varscan2
- CFD | c.708G>A p.G236= | Silent (SNP) | VAF 209/607 reads (34%) | called by muse, mutect2, varscan2
- CHRM3 | c.1773G>A p.*591= | Silent (SNP) | VAF 58/226 reads (26%) | catalogued as COSV99697232; called by muse, mutect2, varscan2
- CHRNB1 | c.981C>T p.V327= | Silent (SNP) | VAF 124/453 reads (27%) | catalogued as rs1195435380, COSV60141784; called by muse, mutect2, varscan2
- CLPSL2 | c.243G>A p.R81= | Silent (SNP) | VAF 111/695 reads (16%) | catalogued as rs190920712; called by muse, mutect2, varscan2
- COMMD5 | c.312G>A p.L104= | Silent (SNP) | VAF 177/566 reads (31%) | called by muse, mutect2, varscan2
- CPNE7 | c.1266G>A p.E422= | Silent (SNP) | VAF 90/345 reads (26%) | called by muse, mutect2, varscan2
- CYP2C9 | c.378C>T p.F126= | Silent (SNP) | VAF 128/331 reads (39%) | called by muse, mutect2, varscan2
- DIAPH1 | c.337T>C p.L113= | Silent (SNP) | VAF 90/303 reads (30%) | called by muse, mutect2, varscan2
- DNAH10 | c.726G>A p.P242= (on ENST00000409039; = p.P181= on NM_207437.3) | Silent (SNP) | VAF 100/456 reads (22%) | catalogued as rs1036807138; called by muse, mutect2, varscan2
- ERC2 | c.768C>T p.I256= | Silent (SNP) | VAF 133/480 reads (28%) | catalogued as rs376629102; called by muse, mutect2, varscan2
- FAM155A | c.579G>A p.R193= | Silent (SNP) | VAF 160/363 reads (44%) | catalogued as COSV65554535; called by muse, mutect2, varscan2
- GP5 | c.1488G>A p.L496= | Silent (SNP) | VAF 188/592 reads (32%) | called by muse, mutect2, varscan2
- GPC6 | c.99C>T p.V33= | Silent (SNP) | VAF 165/359 reads (46%) | called by muse, mutect2, varscan2
- GRIA1 | c.324C>T p.F108= | Silent (SNP) | VAF 108/403 reads (27%) | catalogued as COSV99597383; called by muse, mutect2, varscan2
- H2BW2 | c.423C>T p.A141= | Silent (SNP) | VAF 98/144 reads (68%) | called by muse, mutect2, varscan2
- HMCN1 | c.16665T>C p.V5555= | Silent (SNP) | VAF 144/422 reads (34%) | called by muse, mutect2, varscan2
- HSD17B2 | c.744G>A p.L248= | Silent (SNP) | VAF 132/493 reads (27%) | called by muse, mutect2, varscan2
- IFNGR1 | c.1396C>T p.L466= | Silent (SNP) | VAF 77/337 reads (23%) | called by muse, mutect2, varscan2
- IFNL2 | c.144C>T p.S48= | Silent (SNP) | VAF 148/568 reads (26%) | catalogued as rs373005397; called by muse, mutect2, varscan2
- IGHV1-46 | c.273G>A p.R91= | Silent (SNP) | VAF 120/376 reads (32%) | catalogued as rs782430853; called by muse, mutect2, varscan2
- IGSF21 | c.859C>T p.L287= | Silent (SNP) | VAF 165/363 reads (45%) | catalogued as rs71645408; called by muse, mutect2, varscan2
- IL2RG | c.108C>T p.T36= | Silent (SNP) | VAF 93/193 reads (48%) | called by muse, mutect2, varscan2
- KALRN | c.1348C>T p.L450= | Silent (SNP) | VAF 116/384 reads (30%) | catalogued as rs1355963080; called by muse, mutect2, varscan2
- KCTD16 | c.471C>T p.L157= | Silent (SNP) | VAF 174/529 reads (33%) | called by muse, mutect2, varscan2
- KRT4 | c.786G>T p.V262= | Silent (SNP) | VAF 126/434 reads (29%) | called by muse, mutect2, varscan2
- LPA | c.2613C>T p.I871= | Silent (SNP) | VAF 72/188 reads (38%) | catalogued as rs759225410, COSV60313781; called by muse, mutect2, varscan2
- MCTP2 | c.2352G>A p.R784= | Silent (SNP) | VAF 60/201 reads (30%) | called by muse, mutect2, varscan2
- MUC16 | c.16560C>T p.S5520= | Silent (SNP) | VAF 135/487 reads (28%) | catalogued as rs773830928; called by muse, mutect2, varscan2
- MYO18B | c.1866G>A p.G622= | Silent (SNP) | VAF 91/298 reads (31%) | called by muse, mutect2, varscan2
- MYOCD | c.312C>T p.L104= | Silent (SNP) | VAF 108/418 reads (26%) | catalogued as rs146494556; called by muse, varscan2
- NECTIN1 | c.312C>T p.F104= | Silent (SNP) | VAF 171/378 reads (45%) | catalogued as rs1343442607; called by muse, mutect2, varscan2
- NOC2L | c.510C>T p.F170= | Silent (SNP) | VAF 136/271 reads (50%) | called by muse, mutect2, varscan2
- NOL6 | c.1755C>T p.S585= | Silent (SNP) | VAF 134/276 reads (49%) | catalogued as COSV53044990; called by muse, mutect2, varscan2
- NUP35 | c.426C>T p.I142= | Silent (SNP) | VAF 77/306 reads (25%) | catalogued as rs775269889; called by muse, mutect2, varscan2
- NUTM1 | c.201C>T p.P67= | Silent (SNP) | VAF 93/367 reads (25%) | catalogued as rs750888502; called by muse, varscan2
- OR10H4 | c.714G>A p.K238= | Silent (SNP) | VAF 156/498 reads (31%) | called by muse, mutect2, varscan2
- OR2B6 | c.600C>T p.F200= | Silent (SNP) | VAF 154/376 reads (41%) | catalogued as COSV55129908; called by muse, mutect2, varscan2
- OR4D2 | c.66G>A p.E22= | Silent (SNP) | VAF 120/386 reads (31%) | catalogued as COSV101613852; called by muse, mutect2, varscan2
- OR5BS1P | c.294C>T p.F98= | Silent (SNP) | VAF 107/338 reads (32%) | called by muse, mutect2, varscan2
- PAPPA | c.1758C>T p.P586= | Silent (SNP) | VAF 149/438 reads (34%) | catalogued as rs57672573; called by muse, mutect2, varscan2
- POTEC | c.465G>A p.K155= | Silent (SNP) | VAF 144/540 reads (27%) | catalogued as rs1250961403, COSV62801102; called by muse, mutect2, varscan2
- POTEI | c.474C>T p.I158= | Silent (SNP) | VAF 42/222 reads (19%) | catalogued as rs1168223406; called by muse, mutect2, varscan2
- POTEJ | c.363C>T p.I121= | Silent (SNP) | VAF 38/334 reads (11%) | called by muse, mutect2
- PPP2R2C | c.1272G>A p.E424= | Silent (SNP) | VAF 131/337 reads (39%) | catalogued as COSV59446765; called by muse, mutect2, varscan2
- PROCR | c.117C>T p.P39= | Silent (SNP) | VAF 135/418 reads (32%) | called by muse, mutect2, varscan2
- PRSS21 | c.360C>T p.F120= | Silent (SNP) | VAF 104/368 reads (28%) | catalogued as rs758836098, COSV50052135; called by muse, mutect2, varscan2
- PRSS38 | c.90C>T p.V30= | Silent (SNP) | VAF 135/512 reads (26%) | catalogued as rs774229501, COSV64539534; called by muse, varscan2
- PRSS58 | c.351G>A p.V117= | Silent (SNP) | VAF 500/719 reads (70%) | catalogued as rs1189189318, COSV73488436; called by muse, mutect2, varscan2
- PYGB | c.309G>C p.L103= | Silent (SNP) | VAF 113/463 reads (24%) | called by muse, mutect2, varscan2
- RASGRF1 | c.447C>T p.I149= | Silent (SNP) | VAF 112/411 reads (27%) | catalogued as COSV69178328; called by muse, mutect2, varscan2
- RPTN | c.1665G>A p.Q555= | Silent (SNP) | VAF 219/790 reads (28%) | catalogued as COSV60167674; called by muse, mutect2, varscan2
- SBK3 | c.258G>A p.R86= | Silent (SNP) | VAF 144/515 reads (28%) | called by muse, mutect2, varscan2
- SCN4A | c.2142C>T p.F714= | Silent (SNP) | VAF 171/552 reads (31%) | catalogued as rs763015471, COSV71129834; called by muse, mutect2, varscan2
- SLC12A3 | c.2655G>A p.K885= (on ENST00000563236 / NM_001126108.2; = p.K894= on NM_000339.3) | Silent (SNP) | VAF 85/321 reads (26%) | called by muse, mutect2, varscan2
- SLC25A36 | c.255C>T p.G85= | Silent (SNP) | VAF 61/283 reads (22%) | catalogued as rs1244802381; called by muse, mutect2, varscan2
- SLC8A2 | c.153G>A p.P51= | Silent (SNP) | VAF 184/648 reads (28%) | catalogued as rs751102582, COSV52637674, COSV99370007; called by muse, varscan2
- SLCO1B3 | c.216C>T p.S72= | Silent (SNP) | VAF 48/195 reads (25%) | catalogued as rs1007686555; called by muse, mutect2, varscan2
- SPAG17 | c.6414G>A p.L2138= | Silent (SNP) | VAF 160/414 reads (39%) | called by muse, mutect2, varscan2
- SPHKAP | c.2979G>A p.R993= | Silent (SNP) | VAF 123/484 reads (25%) | catalogued as COSV60867997; called by muse, mutect2, varscan2
- SPTBN1 | c.384C>T p.V128= | Silent (SNP) | VAF 131/496 reads (26%) | called by muse, mutect2, varscan2
- TEX15 | c.5563C>T p.L1855= (on ENST00000256246; = p.L2238= on NM_001350162.2) | Silent (SNP) | VAF 105/385 reads (27%) | called by muse, mutect2, varscan2
- TIAM1 | c.489G>A p.A163= | Silent (SNP) | VAF 136/661 reads (21%) | catalogued as rs761789657, COSV54566350; called by muse, mutect2, varscan2
- TMEM132C | c.429C>T p.S143= | Silent (SNP) | VAF 119/475 reads (25%) | called by muse, mutect2, varscan2
- TRRAP | c.10203C>T p.A3401= (on ENST00000359863 / NM_001244580.1; = p.A3372= on NM_003496.3) | Silent (SNP) | VAF 217/649 reads (33%) | catalogued as rs769399893; called by muse, mutect2, varscan2
- UNC45A | c.1264C>T p.L422= | Silent (SNP) | VAF 183/611 reads (30%) | called by muse, mutect2, varscan2
- UNC45A | c.1893C>T p.F631= | Silent (SNP) | VAF 84/275 reads (31%) | catalogued as rs756225538; called by muse, mutect2, varscan2
- URB2 | c.549C>T p.I183= | Silent (SNP) | VAF 134/487 reads (28%) | called by muse, mutect2, varscan2
- VWF | c.5658G>A p.E1886= | Silent (SNP) | VAF 101/360 reads (28%) | called by muse, mutect2, varscan2
- XPO6 | c.2793C>T p.S931= | Silent (SNP) | VAF 77/277 reads (28%) | catalogued as rs1214046206; called by muse, mutect2, varscan2
- ZC3HAV1 | c.564C>T p.L188= | Silent (SNP) | VAF 440/615 reads (72%) | catalogued as rs1346510083, COSV54299131, COSV99648972; called by muse, mutect2, varscan2
- ZFPM2 | c.1017C>T p.V339= | Silent (SNP) | VAF 118/348 reads (34%) | catalogued as COSV101023062; called by muse, mutect2, varscan2
- ZFYVE26 | c.6909C>T p.L2303= | Silent (SNP) | VAF 169/518 reads (33%) | called by muse, mutect2, varscan2
- ZNF341 | c.813C>T p.F271= | Silent (SNP) | VAF 157/506 reads (31%) | catalogued as COSV61010264; called by muse, varscan2
- ZNF99 | c.177G>A p.G59= | Silent (SNP) | VAF 79/317 reads (25%) | catalogued as COSV101233724; called by muse, mutect2, varscan2
- AL353804.7 | chrX:73846693 C>T | 5'Flank (SNP) | VAF 109/199 reads (55%) | catalogued as rs765966307; called by muse, mutect2, varscan2
- ARHGEF4 | c.428-16052G>A | Intron (SNP) | VAF 78/294 reads (27%) | catalogued as rs546838842; called by muse, mutect2, varscan2
- CPLANE1 | c.*2291C>T | 3'UTR (SNP) | VAF 126/437 reads (29%) | called by muse, mutect2, varscan2
- KCTD1 | c.-15-46461G>A | Intron (SNP) | VAF 104/372 reads (28%) | called by muse, varscan2
- PDE4B | c.635-52G>A | Intron (SNP) | VAF 163/355 reads (46%) | called by muse, mutect2, varscan2
- PSG9 | c.1243+89C>A | Intron (SNP) | VAF 109/353 reads (31%) | called by muse, mutect2, varscan2
- RN7SL495P | chr15:22613420 C>T | 5'Flank (SNP) | VAF 37/259 reads (14%) | catalogued as rs1378622671; called by muse, mutect2, varscan2
- SULT1A2 | c.275-34C>A | Intron (SNP) | VAF 195/576 reads (34%) | called by muse, mutect2, varscan2
- TUT1 | chr11:62591580 G>A | 5'Flank (SNP) | VAF 97/229 reads (42%) | catalogued as rs866530324, COSV53468635; called by muse, mutect2, varscan2
- Z99774.2 | chr22:26671005 G>A | 5'Flank (SNP) | VAF 93/297 reads (31%) | called by muse, mutect2, varscan2
- ZNF812P | n.1023G>T | RNA (SNP) | VAF 74/266 reads (28%) | called by muse, mutect2, varscan2
